Somatic mutation profile of tumor specimen 0DIMX2 from CCDI case PBBVRY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Epididymis; Age at diagnosis: 20.8 years (7,612 days).
Specimen 0DIMX2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1ef529b-2df6-432b-a4af-5e327b443d2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5692e40d-accc-4c4d-8959-0cfbaca356d1

The open-access MAF lists 187 somatic variants for this specimen: 112 protein-altering or splice-affecting, 38 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 38, Intron 17, 3'UTR 13, Nonsense Mutation 7, 5'UTR 4, Splice Site 3, 3'Flank 2, Frame Shift Ins 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCT7 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 152/908 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs587777929, CM1311994; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASH2L | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 462/1748 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs762664012, COSV51700338; called by muse, varscan2
- AXDND1 | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 88/878 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62640603, COSV62642324; called by muse, mutect2, varscan2
- BARD1 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 76/1868 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1378818781; ClinVar: uncertain significance; called by muse, mutect2
- BCR | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 358/781 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as rs751622658; called by muse, mutect2, varscan2
- C9orf40 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 105/651 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs568399425; called by muse, varscan2
- CEP162 | c.3451C>G p.P1151A | Missense Mutation (SNP) | VAF 62/2425 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV57620099; called by muse, mutect2
- CLCNKA | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 50/1100 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.201); catalogued as rs387907409; called by muse, mutect2
- CLUH | c.409G>C p.D137H (on ENST00000435359; = p.D175H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/595 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771664686; called by muse, mutect2, varscan2
- CRHR2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 185/2118 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1303136890, COSV59268955; called by muse, mutect2
- CTNNA1 | c.1836C>G p.I612M | Missense Mutation (SNP) | VAF 181/1378 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV57078846; called by muse, mutect2, varscan2
- CTNS | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 324/1077 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as CM992156; called by muse, mutect2, varscan2
- CUL5 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 252/928 reads (27%) | catalogued as COSV67608703; called by mutect2, varscan2
- DISP3 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 40/779 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV53834315; called by muse, mutect2
- DTD2 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 30/1194 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs973108054, COSV60428635; called by muse, mutect2
- EPPK1 | c.6359C>A p.P2120Q | Missense Mutation (SNP) | VAF 341/936 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.681); catalogued as rs1554659234; called by muse, mutect2, varscan2
- EYS | c.6836C>A p.A2279E | Missense Mutation (SNP) | VAF 212/1524 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as COSV101012972, COSV65466307; called by mutect2, varscan2
- GJA8 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 121/485 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs142026480, CM146420, COSV53787651; called by muse, mutect2, varscan2
- GRIN2A | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 599/1166 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58020344; called by muse, mutect2, varscan2
- HDAC4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 291/1294 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs1180905679, COSV61862078; called by muse, mutect2, varscan2
- HFE | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 103/2066 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs28934889, CM994469; ClinVar: benign; called by muse, mutect2
- HTATIP2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 439/866 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs748188484, COSV70041187; called by muse, mutect2, varscan2
- HUWE1 | c.12020G>A p.R4007H | Missense Mutation (SNP) | VAF 236/606 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1556914313; called by muse, mutect2, varscan2
- IRS4 | c.478G>C p.A160P | Missense Mutation (SNP) | VAF 209/557 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64534052; called by muse, mutect2, varscan2
- ITGA2 | c.502+1G>A p.X168_splice | Splice Site (SNP) | VAF 153/1057 reads (14%) | catalogued as rs748653916, COSV56855871; called by muse, mutect2, varscan2
- KIF1A | c.4240C>T p.R1414W (on ENST00000320389 / NM_001379639.1; = p.R1406W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/737 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as rs755721997; called by muse, mutect2, varscan2
- MAP1LC3A | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 110/1274 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV54164717; called by muse, mutect2
- MAP4K2 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 331/687 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1015548924; called by muse, mutect2, varscan2
- MOV10L1 | c.2012C>T p.T671M | Missense Mutation (SNP) | VAF 189/1025 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); catalogued as rs776533800; called by muse, varscan2
- NTSR2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 156/791 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs752482430, COSV60991850, COSV60993127; called by muse, mutect2, varscan2
- PHB2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 164/1932 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1565590009, COSV54644091; called by muse, mutect2
- PTHLH | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 344/2563 reads (13%) | catalogued as CM166082, COSV52367272; called by muse, mutect2, varscan2
- RADIL | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 102/1330 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as rs199542721; called by muse, mutect2
- RNF17 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 189/1365 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV55041748; called by muse, mutect2, varscan2
- SCN3A | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 463/2059 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51801775; called by muse, mutect2, varscan2
- SETD2 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 226/1247 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs975806896; called by muse, mutect2, varscan2
- SIGLEC9 | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 59/642 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51583264; called by muse, mutect2
- SLC22A10 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 113/523 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as rs1254101105; called by muse, mutect2, varscan2
- SLITRK2 | c.2404G>A p.V802I | Missense Mutation (SNP) | VAF 275/678 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as rs1556945284, COSV59426311; called by muse, varscan2
- SORCS3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 22/713 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1393848719; called by muse, mutect2
- SPTBN1 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 148/924 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); catalogued as rs775058180, COSV61684973, COSV61694709; called by muse, mutect2, varscan2
- STX18 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 216/839 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1419617078; called by muse, mutect2, varscan2
- TNKS | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 298/1905 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs377231324; called by muse, mutect2, varscan2
- UPP1 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 128/1705 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1032539780; called by muse, mutect2
- ZNF609 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 301/560 reads (54%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs1395493021; called by muse, mutect2, varscan2
- ZNRF3 | c.2468G>A p.R823Q (on ENST00000544604 / NM_001206998.2; = p.R723Q on NM_032173.3) | Missense Mutation (SNP) | VAF 57/584 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs1375956230; called by muse, mutect2
- ABRAXAS1 | c.681+1G>A p.X227_splice | Splice Site (SNP) | VAF 23/690 reads (3%) | called by muse, mutect2
- ALKBH4 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 213/917 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ALMS1 | c.1122C>A p.D374E | Missense Mutation (SNP) | VAF 76/1348 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); called by muse, mutect2
- ANKRD30B | c.2576T>C p.M859T | Missense Mutation (SNP) | VAF 82/529 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ANKS3 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 138/668 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ANO9 | c.2295G>T p.M765I | Missense Mutation (SNP) | VAF 271/570 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP35 | c.3081C>A p.S1027R | Missense Mutation (SNP) | VAF 88/936 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.022); called by muse, mutect2
- ATAD5 | c.5257C>G p.R1753G | Missense Mutation (SNP) | VAF 163/1017 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ATR | c.1968C>A p.Y656* | Nonsense Mutation (SNP) | VAF 277/1358 reads (20%) | called by muse, mutect2, varscan2
- BARX1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 26/956 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BEND6 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 399/1304 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BHLHE41 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 58/884 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- C5AR2 | c.844G>C p.A282P | Missense Mutation (SNP) | VAF 64/902 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- CACNG8 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CC2D1A | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 191/814 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC151 | c.1662G>T p.K554N | Missense Mutation (SNP) | VAF 128/1144 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCDC9 | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 111/614 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CD163 | c.2681A>C p.Q894P | Missense Mutation (SNP) | VAF 157/1047 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CKAP5 | c.4773G>T p.Q1591H | Missense Mutation (SNP) | VAF 169/823 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL11A1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 188/754 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- DNAJC5 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 142/1560 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DOCK2 | c.2320T>C p.F774L | Missense Mutation (SNP) | VAF 79/1524 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.116); called by muse, mutect2
- DUSP15 | c.286G>T p.V96L (on ENST00000278979 / NM_001320479.1; = p.V99L on NM_080611.4) | Missense Mutation (SNP) | VAF 36/1292 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- DYNC1H1 | c.6391C>A p.L2131I | Missense Mutation (SNP) | VAF 37/947 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.031); called by muse, mutect2
- ELAPOR1 | c.1151C>A p.P384Q | Missense Mutation (SNP) | VAF 200/838 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM13C | c.1565G>C p.R522T | Missense Mutation (SNP) | VAF 291/1532 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO38 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 167/1137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXW7 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 108/1376 reads (8%) | called by muse, mutect2
- FKBPL | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 188/685 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GASK1B | c.1088A>C p.E363A | Missense Mutation (SNP) | VAF 32/1161 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMGXB4 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 84/1480 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IQCM | c.439del p.M147Wfs*39 | Frame Shift Del (DEL) | VAF 199/992 reads (20%) | called by mutect2, pindel, varscan2
- ISLR2 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 109/408 reads (27%) | called by muse, mutect2, varscan2
- ITPKC | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 114/1074 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KAT6A | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 42/1690 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRCOL1 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 186/797 reads (23%) | PolyPhen probably damaging (0.995); called by muse, mutect2
- MIA2 | c.690A>C p.E230D | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2
- MUC16 | c.18701C>A p.S6234Y | Missense Mutation (SNP) | VAF 44/1582 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2
- MYG1 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 224/732 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- NCR1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 280/1220 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NPSR1 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 174/2218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- OBSCN | c.16700C>A p.S5567Y | Missense Mutation (SNP) | VAF 109/948 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PDCD2 | c.239T>C p.F80S | Missense Mutation (SNP) | VAF 161/937 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PER1 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 235/930 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- PKHD1L1 | c.3871G>T p.D1291Y | Missense Mutation (SNP) | VAF 260/2512 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.232); called by muse, mutect2
- PLA2G2D | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PLK2 | c.2012dup p.N671Kfs*15 | Frame Shift Ins (INS) | VAF 211/1787 reads (12%) | called by mutect2, pindel, varscan2
- POM121L2 | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 207/1348 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- PREB | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 249/1037 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RABL6 | c.2082dup p.P695Afs*12 | Frame Shift Ins (INS) | VAF 117/595 reads (20%) | called by mutect2, pindel, varscan2
- RCOR1 | c.840C>G p.N280K | Missense Mutation (SNP) | VAF 26/997 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.041); called by muse, mutect2
- RGS22 | c.2503T>C p.S835P | Missense Mutation (SNP) | VAF 84/1927 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- S1PR4 | c.607C>A p.R203S | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- SPAG1 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 83/1931 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TMEM62 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 181/854 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- TRPV4 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 72/850 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); called by muse, mutect2
- UBA3 | c.347+1G>T p.X116_splice | Splice Site (SNP) | VAF 142/816 reads (17%) | called by mutect2, varscan2
- UBL7 | c.1106C>A p.A369E | Missense Mutation (SNP) | VAF 274/542 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- VAMP3 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 92/1038 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); called by muse, mutect2
- WARS2 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 234/867 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR62 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 117/1322 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF229 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 167/1311 reads (13%) | called by muse, mutect2, varscan2
- ZNF230 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 260/1020 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZNF274 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 176/636 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- ZNF318 | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 184/710 reads (26%) | called by muse, mutect2, varscan2
- ZSCAN5B | c.471T>A p.D157E | Missense Mutation (SNP) | VAF 94/1180 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- A2M | c.1122G>A p.G374= | Silent (SNP) | VAF 66/1785 reads (4%) | called by muse, mutect2
- ACTL6B | c.843A>T p.T281= | Silent (SNP) | VAF 86/870 reads (10%) | catalogued as rs759349574; called by mutect2, varscan2
- ADGRV1 | c.846A>G p.P282= | Silent (SNP) | VAF 52/1812 reads (3%) | called by muse, mutect2
- ADH4 | c.948C>A p.I316= | Silent (SNP) | VAF 445/942 reads (47%) | called by muse, mutect2, varscan2
- AFDN | c.1479G>A p.A493= | Silent (SNP) | VAF 142/1272 reads (11%) | catalogued as rs780954787, COSV60039466; called by muse, mutect2, varscan2
- ANKRD46 | c.573C>A p.G191= | Silent (SNP) | VAF 483/2056 reads (23%) | called by mutect2, varscan2
- ARHGAP10 | c.828A>G p.E276= | Silent (SNP) | VAF 26/1079 reads (2%) | called by muse, mutect2
- ARHGEF12 | c.1548G>T p.R516= | Silent (SNP) | VAF 117/1178 reads (10%) | called by muse, mutect2
- ARL11 | c.66G>A p.S22= | Silent (SNP) | VAF 117/1013 reads (12%) | catalogued as rs371976896; called by muse, mutect2, varscan2
- BCS1L | c.543T>C p.Y181= | Silent (SNP) | VAF 34/1241 reads (3%) | called by muse, mutect2
- CACNA1B | c.4734G>T p.L1578= | Silent (SNP) | VAF 154/629 reads (24%) | catalogued as rs1159557881; called by muse, mutect2, varscan2
- CEP170B | c.1725C>T p.T575= (on ENST00000453495; = p.T504= on NM_015005.3) | Silent (SNP) | VAF 320/830 reads (39%) | catalogued as rs892181973; called by muse, mutect2
- CNDP2 | c.879G>A p.A293= | Silent (SNP) | VAF 137/489 reads (28%) | catalogued as rs777738255, COSV60840971; called by muse, mutect2, varscan2
- CNTNAP3 | c.3279T>C p.F1093= | Silent (SNP) | VAF 202/995 reads (20%) | called by muse, mutect2, varscan2
- CUL9 | c.2610C>A p.G870= | Silent (SNP) | VAF 758/1379 reads (55%) | called by muse, mutect2, varscan2
- FBN3 | c.4149C>A p.G1383= | Silent (SNP) | VAF 146/1277 reads (11%) | called by muse, mutect2, varscan2
- FER1L6 | c.999C>T p.D333= | Silent (SNP) | VAF 415/1962 reads (21%) | catalogued as rs377554619; called by muse, mutect2, varscan2
- GALNT2 | c.1377T>G p.T459= | Silent (SNP) | VAF 74/2872 reads (3%) | called by muse, mutect2
- HMBOX1 | c.531C>A p.I177= | Silent (SNP) | VAF 222/1346 reads (16%) | called by muse, mutect2, varscan2
- INSR | c.1032C>G p.G344= | Silent (SNP) | VAF 160/1852 reads (9%) | catalogued as COSV57175959; called by muse, mutect2
- ITGA8 | c.1140C>T p.T380= | Silent (SNP) | VAF 165/934 reads (18%) | catalogued as rs748377171, COSV65223864; called by muse, mutect2, varscan2
- JAK2 | c.1392C>A p.L464= | Silent (SNP) | VAF 524/1083 reads (48%) | catalogued as COSV101078010; called by muse, mutect2, varscan2
- KLHL26 | c.1689C>T p.I563= | Silent (SNP) | VAF 53/506 reads (10%) | catalogued as rs774110990, COSV56316425; called by muse, mutect2, varscan2
- LRP1B | c.7215A>G p.P2405= | Silent (SNP) | VAF 148/1005 reads (15%) | called by muse, mutect2, varscan2
- LY75 | c.2289A>G p.R763= | Silent (SNP) | VAF 220/1129 reads (19%) | called by muse, mutect2, varscan2
- MAP1A | c.3039C>G p.S1013= | Silent (SNP) | VAF 22/850 reads (3%) | called by muse, mutect2
- MCM9 | c.513G>A p.S171= | Silent (SNP) | VAF 159/1506 reads (11%) | catalogued as rs144849604; called by muse, mutect2, varscan2
- MUC1 | c.3300G>A p.K1100= (on ENST00000611571 / NM_001371720.1; = p.K111= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 1044/1427 reads (73%) | called by muse, mutect2, varscan2
- NCOA3 | c.2094A>C p.V698= | Silent (SNP) | VAF 81/825 reads (10%) | called by muse, mutect2
- NLRP3 | c.318C>T p.C106= | Silent (SNP) | VAF 98/2136 reads (5%) | catalogued as COSV60220518; called by muse, mutect2
- NUP133 | c.115C>T p.L39= | Silent (SNP) | VAF 34/1170 reads (3%) | called by muse, mutect2
- NWD1 | c.240G>A p.S80= | Silent (SNP) | VAF 144/1434 reads (10%) | catalogued as rs779216711; called by muse, mutect2
- PSG3 | c.1146C>G p.P382= | Silent (SNP) | VAF 99/1961 reads (5%) | catalogued as COSV59506588; called by muse, mutect2
- RYR3 | c.6651G>T p.V2217= | Silent (SNP) | VAF 216/880 reads (25%) | called by muse, mutect2, varscan2
- SLC39A7 | c.915C>T p.N305= | Silent (SNP) | VAF 68/2234 reads (3%) | catalogued as rs751776284; called by muse, mutect2
- SLIT1 | c.2772C>A p.A924= | Silent (SNP) | VAF 162/472 reads (34%) | called by muse, mutect2, varscan2
- SPAG17 | c.3399G>A p.S1133= | Silent (SNP) | VAF 278/1170 reads (24%) | catalogued as rs370528649; called by muse, mutect2, varscan2
- TRPT1 | c.261C>T p.F87= (on ENST00000317459 / NM_001160393.1; = p.F38= on NM_031472.4) | Silent (SNP) | VAF 147/565 reads (26%) | catalogued as rs754969203; called by muse, mutect2, varscan2
- AGAP3 | c.224-1436G>T | Intron (SNP) | VAF 120/657 reads (18%) | called by muse, mutect2
- ANKRD22 | c.*2340G>T | 3'UTR (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2
- ATP6V1B2 | c.1162-51C>A | Intron (SNP) | VAF 154/1113 reads (14%) | called by muse, mutect2, varscan2
- CCDC15 | c.2734+12G>T | Intron (SNP) | VAF 147/630 reads (23%) | called by muse, mutect2, varscan2
- CCR5 | c.*94T>A | 3'UTR (SNP) | VAF 52/121 reads (43%) | catalogued as COSV99433491; called by muse, mutect2, varscan2
- CLEC4E | c.*98G>T | 3'UTR (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2
- CRIP3 | c.*18dup | 3'UTR (INS) | VAF 50/288 reads (17%) | catalogued as rs745781004; called by mutect2, varscan2
- CRYBA2 | c.303+78C>A | Intron (SNP) | VAF 153/590 reads (26%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-35+721C>T | Intron (SNP) | VAF 34/96 reads (35%) | catalogued as rs748821029; called by muse, varscan2
- ERP29 | c.-7C>T | 5'UTR (SNP) | VAF 72/810 reads (9%) | catalogued as rs1377353453; called by muse, mutect2
- EZR | c.*57C>T | 3'UTR (SNP) | VAF 76/423 reads (18%) | called by muse, mutect2, varscan2
- FIGNL2 | c.*23_*24insGGACGG | 3'UTR (INS) | VAF 65/279 reads (23%) | called by mutect2, pindel, varscan2
- GPR173 | c.-94C>A | 5'UTR (SNP) | VAF 60/159 reads (38%) | called by muse, mutect2, varscan2
- GUK1 | c.113-33C>A | Intron (SNP) | VAF 22/739 reads (3%) | called by muse, mutect2
- HMG20B | c.473-34G>T | Intron (SNP) | VAF 32/268 reads (12%) | called by muse, varscan2
- KIF9 | c.1289+95C>A | Intron (SNP) | VAF 107/242 reads (44%) | called by muse, mutect2, varscan2
- LCP2 | c.523+31G>A | Intron (SNP) | VAF 108/721 reads (15%) | catalogued as rs535999005; called by muse, mutect2, varscan2
- NAF1 | chr4:163126922 T>G | 3'Flank (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2
- NECTIN1 | c.1003+607G>C | Intron (SNP) | VAF 247/465 reads (53%) | called by muse, mutect2, varscan2
- NPBWR1 | c.-72C>A | 5'UTR (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- OR13J1 | c.*8C>T | 3'UTR (SNP) | VAF 77/303 reads (25%) | catalogued as rs1256668859, COSV100940853; called by muse, mutect2, varscan2
- OR2AT4 | c.*9T>C | 3'UTR (SNP) | VAF 42/637 reads (7%) | called by muse, mutect2
- PALLD | c.1965-12998C>T | Intron (SNP) | VAF 90/986 reads (9%) | called by muse, mutect2
- PCNX1 | c.604+23T>A | Intron (SNP) | VAF 47/667 reads (7%) | called by muse, mutect2
- PLD2 | c.1921-85C>T | Intron (SNP) | VAF 23/129 reads (18%) | catalogued as rs1043026681; called by muse, mutect2, varscan2
- PNPLA6 | c.28-71C>G | Intron (SNP) | VAF 32/308 reads (10%) | called by muse, mutect2, varscan2
- POMGNT1 | c.*287C>A | 3'UTR (SNP) | VAF 202/871 reads (23%) | called by mutect2, varscan2
- PPFIBP2 | chr11:7656833 G>T | 3'Flank (SNP) | VAF 100/425 reads (24%) | catalogued as rs747406223; called by muse, mutect2, varscan2
- PPP1R11 | c.*18C>A | 3'UTR (SNP) | VAF 134/918 reads (15%) | called by muse, mutect2, varscan2
- PPP2R2B | c.-4C>A | 5'UTR (SNP) | VAF 88/779 reads (11%) | catalogued as COSV101065155; called by muse, mutect2, varscan2
- PSMD9 | c.556-25C>T | Intron (SNP) | VAF 27/199 reads (14%) | catalogued as rs1394585774; called by muse, mutect2, varscan2
- RNF41 | c.362+18C>A | Intron (SNP) | VAF 127/330 reads (38%) | catalogued as rs376947778; called by muse, mutect2, varscan2
- RSF1 | c.734-74A>G | Intron (SNP) | VAF 36/163 reads (22%) | catalogued as rs1384751260; called by muse, mutect2, varscan2
- TATDN3 | chr1:212791859 G>A | 5'Flank (SNP) | VAF 58/536 reads (11%) | called by muse, mutect2, varscan2
- TMPRSS11E | c.*78T>A | 3'UTR (SNP) | VAF 14/274 reads (5%) | catalogued as COSV59517951; called by muse, mutect2
- TRIM38 | c.*75T>C | 3'UTR (SNP) | VAF 79/643 reads (12%) | catalogued as COSV62642909; called by muse, mutect2, varscan2
- TRIML1 | c.*4G>T | 3'UTR (SNP) | VAF 81/962 reads (8%) | called by muse, mutect2
